Gene-level copy-number profile of tumor specimen TCGA-FU-A3NI-01A from TCGA case TCGA-FU-A3NI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 45.3 years (16,533 days).
Specimen TCGA-FU-A3NI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.05f8d093-260b-4a94-bd96-9eae3763b553.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FU-A3NI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e2d9ced9-5bf5-492c-95e1-82fa2b83a1c8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 16,237; copy number 3: 19,401; copy number 4: 17,708; copy number 5: 3,649; copy number 6: 2,347; copy number 7: 238; copy number 8: 40; copy number 10: 44; copy number 11: 46; copy number 15: 70; copy number 29: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FU-A3NI-01A-11D-A21P-01): tumor purity 0.65, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 464 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,860,532–61,533,271, 40 genes, copy number 8 (within-gene range 5–8): DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3.
- chr7:57,770,619–57,837,046, 13 genes, copy number 10: AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr7:64,294,516–67,362,950, 116 genes, copy number 7–11 (broad region; genes not listed).
- chr8:38,901,235–40,402,010, 28 genes, copy number 10 (within-gene range 4–10): PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1.
- chr14:90,061,994–97,158,736, 168 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:35,292,125–35,347,361, 3 genes, copy number 10 (within-gene range 3–10): MAG, CD22, U62631.1.
- chr19:43,278,933–44,949,565, 96 genes, copy number 15–29 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
